Surgical pathology report (de-identified scan), TCGA case TCGA-MQ-A6BR, project TCGA-MESO (Mesothelioma), tissue source site Washington University - NYU, specimen TCGA-MQ-A6BR-01A (Primary Tumor).

[page 1 of 3]
**THIS IS A CONFIDENTIAL AND PRIVILEGED COMMUNICATION
PLEASE DISPOSE OF PAPER COPIES APPROPRIATELY**

Printed by:

Name:

Age:

Test Name: 6TH RIB, LEFT{LEVEL 5 LYMPH NODE{LEVEL 6 LYMPH NODE
{LEVEL 7 LYMPH NODE{LINGULAR BIOPSY{LEFT LOWER LOBE
BIOPSY{NODULE ON PA{PLEURAL TUMOR{PLEURA LEFT

Test Date:

Ordered By:

COLLECTION DATE:

SPECIMEN NUMBER:

SPECIMENS:

1. 6TH RIB, LEFT
2. LEVEL 5 LYMPH NODE
3. LEVEL 6 LYMPH NODE
4. LEVEL 7 LYMPH NODE
5. LINGULAR BIOPSY
6. LEFT LOWER LOBE BIOPSY
7. NODULE ON PA
8. PLEURAL TUMOR
9. PLEURA LEFT

*ICD-O-3
Mesothelioma, epithelioid
(w) solid growth pattern
9052/3
Site Pleura, parietal C38.4
w 5/16/13*

DIAGNOSIS:

1. RIB, SIXTH, LEFT: EXCISION
- RIB, NEGATIVE FOR CARCINOMA.
2. LYMPH NODES, LEVEL FIVE: BIOPSY
- SIX LYMPH NODES, NEGATIVE FOR MALIGNANCY.
3. LYMPH NODES, LEVEL SIX: BIOPSY
- FIBROADIPOSE TISSUE, NEGATIVE FOR MALIGNANCY.
- NO LYMPHOID TISSUE IDENTIFIED.
4. LYMPH NODES, LEVEL SEVEN: BIOPSY
- TWO LYMPH NODES WITH FOCALLY CALCIFIED NECROTIZING GRANULOMA,
NEGATIVE FOR CARCINOMA.
- GMS AND AFB ARE NEGATIVE FOR FUNGAL AND MYCOBACTERIAL ORGANISMS.
5. LINGULA: BIOPSY
- FOCUS OF MALIGNANT MESOTHELIOMA, EPITHELIOID TYPE (0.4),
INVOLVING VISCERAL PLEURA.
- NO LUNG PARENCHYMAL INVASION IDENTIFIED.
6. LUNG, LEFT, LOWER LOBE: TRANSBRONCHIAL BIOPSY / WEDGE RESECTION
- LUNG PARENCHYMA WITH EMPHYSEMATOUS CHANGE, NEGATIVE FOR
MALIGNANCY.
7. NODULE ON PA: BIOPSY
- FIBROADIPOSE AND VASCULAR TISSUE WITH NEUTROPHILIC AGGREGATES
AND FIBRIN, NEGATIVE FOR MALIGNANCY.
8. PLEURA: PLEURECTOMY

IHPAA Discrepancy		✓

[page 2 of 3]
- DIFFUSE MALIGNANT MESOTHELIOMA, EPITHELOID TYPE WITH SOLID GROWTH PATTERN, INVOLVING PARIETAL PLEURA.

9. PLEURA, LEFT: PLEURECTOMY

- DIFFUSE MALIGNANT MESOTHELIOMA, EPITHELOID TYPE WITH SOLID GROWTH PATTERN, INVOLVING PARIETAL PLEURA.

- METASTATIC MALIGNANT MESOTHELIOMA IN ONE OF THREE LYMPH NODES (1/3).

(SUMMARY):

Histologic Type: Epithelioid type, solid growth pattern.

Tumor Extent: The tumor involves the parietal pleura as scattered nodules, with focal visceral involvement (pT1b).

Regional Lymph Nodes: Metastasis in one lymph node (pN1) (specimen 9).

Lymphovascular Invasion: Present.

Pathologic Staging: pT1b N1 Mx

(NOTE): The tumor is positive for calretinin and CK5/6, and negative for BerEP4 and B72.3. The results support the diagnosis.

Pathologist

CLINICAL HISTORY AND PRE - OPERATIVE DIAGNOSIS:
Mesothelioma

MACROSCOPIC DESCRIPTION:

The specimen is received in nine parts each labeled with the patient's name.

1. Part one is received in formalin labeled '6th rib, left'. It consists of two fragments of rib measuring 8.6 x 1.6 x 0.9 cm and 8.7 x 1.7 x 0.6 cm. Representative sections are submitted.

2. Part two is received in saline labeled 'level 5 lymph node'. It consists of multiple pieces of fibroadipose tissue measuring 2.8 x 2.5 x 0.9 cm in aggregate. The specimen is entirely submitted.

3. Part three is received in saline labeled 'level 6 lymph node'. It consists of a piece of fibroadipose tissue measuring 1.1 x 0.6 x 0.4 cm. The specimen is entirely submitted.

4. Part four is received in saline labeled 'level 7 lymph node'. It consists of a piece of black-to-yellow soft tissue measuring 0.8 x 0.8 x 0.4 cm. The specimen is entirely submitted.

5. Part five is received in saline labeled 'lingular biopsy'. It consists of a piece of lung tissue measuring 3.2 x 1.6 x 0.4 cm. There is a suture identified on the specimen; the suture is between two nodules, per surgeon. One of the nodules measures 0.4 x 0.2 cm, the other nodule measuring 0.3 x 0.1 cm. The two nodules are located at the pleural surface. One side of the specimen is stapled. The pleural surface of the specimen is inked blue. The stapled margin is inked green. The specimen is serially sectioned and entirely submitted.

[page 3 of 3]
6. Part six is received in saline labeled 'left lower lobe biopsy'. It consists of a fragment of lung tissue measuring 3.6 x 1.2 x 0.4 cm. One end of the specimen is stapled. There is no nodule identified at the pleural surface. The pleural surface is inked blue and the stapled margin is inked green. The specimen is serially sectioned and entirely submitted.

7. Part seven is received in saline labeled 'nodule on PA'. It consists of a piece of pink soft tissue measuring 0.6 x 0.4 x 0.2 cm. The specimen is wrapped in filter paper and entirely submitted

8. Part eight is received in saline labeled 'pleural tumor'. It consists of a piece of pleura with adipose tissue measuring 21.5 x 0.9 x 0.4 cm. There are three nodules identified at the pleural surface which measuring 1.9 x 1.2 x 0.6 cm, 1.8 x 1.6 x 0.6 cm, and 0.9 x 0.9 x 0.1 cm, cut surface is tan-pink. All three nodules are submitted. Representative sections of the rest of the specimen are also submitted

9. Part nine is received fresh labeled 'pleura left'. It consists of multiple pieces of tan-red soft tissue measuring 15 x 13 x 1.2 cm in aggregate. There are multiple small nodules identified which measure 0.5 to 0.9 cm. Representative sections are submitted.

SUMMARY OF SECTIONS:

1A representative of part one

2A,2B in toto

3A in toto

4A in toto

5A-5D in toto

6A-6D in toto

7A in toto

8A-8D representative of part eight

9A-9I representative of part nine

SPECIAL PROCEDURES:

GMS, AFB (4A)

Calretinin, CK5/6, BerEP4, B72.3 (8A).

Final Diagnosis performed by

Electronically signed

The electronic signature attests that the named Attending Pathologist has evaluated the specimen referred to in the signed section of the report and formulated the diagnosis therein.

This report may include one or more immunohistochemical stain results that use analyte specific reagents.

The tests were developed and their performance characteristics determined by

They have not been cleared or approved by the US Food and Drug Administration.

The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file cac65732-c8b7-4ec8-9e90-b909adc7bcc8 (TCGA-MQ-A6BR.F7C5D3ED-657F-4586-9CEE-F7CA8D37FC54.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).